CCDI case PBBIVU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8e97c82b-700f-48eb-87d6-8d3c1bb5dc76

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.6 years (3,492 days).

Biospecimens (3 samples)
- Sample 0D9JPL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9JPM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0D9JPN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
